Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A5VU, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A5VU-01A (Primary Tumor).

Gross Description: A mass is located in 3rd and 4th toes-feet. It is ulcerated and invasive, with 5x4x1.5cm, firm, brown, black-gray surface

Microscopic Description: Epidermis is ulcerated and necrotic. Tumor is composed of sheets or groups of spindle or oval tumor cells with quite abundant cytoplasm. Sometime, the cytoplasm contains finely divided melanin pigment granulae. Tumor cells have a quite low nucleo-cytoplasmic ratio. Nucleus varies in shape and size with large esinophilic nucleoli. Mitotic figures are common. Tumor is invasion of lymph node, or fat tissue.

Diagnosis Details: Malignant melanoma

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Surgical resection

Tumor site: Skin, foot *Per TSS on 2/18/13, TCGA tumor arose from non-glabrous skin.*

Tumor size: 3 x 3 x 1.5 cm

Tumor features: Ulcerated

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Poorly differentiated

Lymph nodes: 1/5 positive for metastasis (Left inguinal lymph node 1/5)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Breslow Thickness = 15 mm

Comments: None

ICD-O-3
Melanoma, malignant. NOS 8.720/3
Site: Skin, lower extremity C44.7
gn 2/18/13

Source: NCI Genomic Data Commons file 0bd4f112-f33e-4eb5-8111-f92a0277bf11 (TCGA-EB-A5VU.960FB267-8E01-4343-B798-E9A806E55BE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).